Somatic mutation profile of tumor specimen TCGA-29-1705-01A (aliquot TCGA-29-1705-01A-01W-0633-09) from TCGA case TCGA-29-1705, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 48.0 years (17,530 days).
Specimen TCGA-29-1705-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9262a727-dacb-4515-8a6d-bd646b0cc973.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1705-10A (Blood Derived Normal), aliquot TCGA-29-1705-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2867937-1c7a-40f9-bb88-131ec4a92a07

The open-access MAF lists 54 somatic variants for this specimen: 35 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 17, Frame Shift Del 4, Nonsense Mutation 1, Splice Site 1, 3'UTR 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 75/122 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BIN1 | c.337G>C p.D113H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV52117059; called by muse, mutect2, varscan2
- C7 | c.2137T>C p.C713R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762301278, COSV100495866; called by muse, mutect2, varscan2
- C8B | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV100980785; called by muse, mutect2
- CD46 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV59732191; called by muse, mutect2, varscan2
- CDK12 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV101420463; called by muse, mutect2
- CREBBP | c.1170C>G p.N390K | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52117974, COSV52125534; called by muse, mutect2, varscan2
- CYP1A1 | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs1164944044, COSV65696841; called by muse, mutect2, varscan2
- EDIL3 | c.1319A>G p.D440G | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV56888153; called by muse, mutect2, varscan2
- EXOC4 | c.2920G>A p.V974I | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as rs1438763079, COSV54089562; called by muse, mutect2, varscan2
- FGF8 | c.548C>T p.T183M (on ENST00000344255 / NM_033164.4; = p.T165M on NM_006119.6) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1480224305, COSV60142216; called by muse, mutect2
- GAPVD1 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 62/120 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV52921721; called by muse, mutect2, varscan2
- GTF3C4 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.388); catalogued as COSV64645094; called by muse, mutect2, varscan2
- HTATIP2 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV70041105; called by muse, mutect2, varscan2
- IKBKE | c.1963C>T p.Q655* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV65623053; called by muse, mutect2, varscan2
- KLHL40 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs142285083, COSV55133238; called by muse, mutect2
- LAMA3 | c.9352A>G p.S3118G (on ENST00000313654 / NM_198129.4; = p.S1509G on NM_000227.6) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV52532266; called by muse, mutect2, varscan2
- LRPPRC | c.1906C>G p.P636A | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1296912885, COSV53236060; called by muse, mutect2, varscan2
- MFF | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.336); catalogued as COSV58825345, COSV58825530; called by muse, mutect2
- OSBPL11 | c.2075A>G p.K692R | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs1225342289, COSV56173220; called by muse, mutect2, varscan2
- POLR2B | c.1069T>A p.C357S | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.431); catalogued as COSV58899422; called by muse, mutect2, varscan2
- PTPRS | c.46A>G p.M16V | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53614508; called by muse, mutect2, varscan2
- SALL1 | c.2684G>T p.G895V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV51755217; called by muse, mutect2, varscan2
- SOGA1 | c.2897G>C p.G966A | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV52914441; called by muse, mutect2, varscan2
- TRDMT1 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58318723; called by muse, mutect2, varscan2
- TUBGCP6 | c.1999A>G p.I667V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.624); catalogued as COSV50539421; called by muse, mutect2, varscan2
- ZBTB21 | c.2751G>A p.M917I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60403579; called by muse, mutect2, varscan2
- ZNF677 | c.1333A>T p.S445C | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100447963; called by muse, mutect2, varscan2
- FGD2 | c.527+3_527+7del p.X176_splice | Splice Site (DEL) | VAF 8/25 reads (32%) | called by pindel, varscan2
- IGHV4-34 | c.294_325del p.D98Efs*? | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by mutect2, pindel
- IGKV1-17 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 216/432 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- LAMA3 | c.3137_3140del p.Y1046* | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- MAST2 | c.5273_5298del p.P1758Qfs*3 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, pindel
- RFX4 | c.540_587del p.F181_E196del (on ENST00000392842 / NM_213594.3; = p.F87_E102del on NM_032491.6) | In Frame Del (DEL) | VAF 132/347 reads (38%) | called by mutect2, pindel
- TRIM22 | c.230_266del p.I77Rfs*45 | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | called by mutect2, pindel
- ADAM12 | c.2505C>A p.P835= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV64126223; called by mutect2, varscan2
- ADARB1 | c.867G>A p.A289= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs557891335, COSV62343033; called by muse, mutect2, varscan2
- AHNAK | c.606G>C p.G202= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs772051984, COSV57208023, COSV57208195; called by muse, mutect2, varscan2
- AL031777.2 | c.111G>A p.K37= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs767965602, COSV61911725; called by muse, mutect2, varscan2
- CRADD | c.90C>G p.L30= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV60552724; called by muse, mutect2, varscan2
- DPP10 | c.1656C>G p.P552= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV59674948, COSV59736802; called by muse, mutect2, varscan2
- FGD2 | c.519G>C p.L173= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV51462801; called by muse, varscan2
- GLDN | c.516A>G p.G172= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs746814257, COSV59089341; called by muse, mutect2, varscan2
- LRFN2 | c.813C>A p.L271= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV57825318; called by muse, mutect2, varscan2
- ORC5 | c.1065A>G p.K355= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV52397510; called by muse, mutect2, varscan2
- PASK | c.1053C>G p.L351= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV52150430; called by muse, varscan2
- PPP1R3F | c.1968T>C p.N656= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as COSV50017896; called by muse, mutect2, varscan2
- RCOR1 | c.1335T>G p.G445= | Silent (SNP) | VAF 63/268 reads (24%) | catalogued as rs766272177, COSV51766794; called by muse, mutect2, varscan2
- SERPINB4 | c.108A>G p.S36= | Silent (SNP) | VAF 58/287 reads (20%) | catalogued as rs1468821972, COSV61984538; called by muse, mutect2, varscan2
- ZNF283 | c.1731G>A p.G577= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV61030801; called by muse, mutect2, varscan2
- ZNF677 | c.1332A>T p.S444= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV100447965; called by muse, mutect2, varscan2
- ZNF80 | c.324G>A p.V108= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV57360225; called by muse, mutect2, varscan2
- EIF3B | c.*204G>A | 3'UTR (SNP) | VAF 7/14 reads (50%) | catalogued as rs377583925; called by muse, mutect2, varscan2
- SULT2B1 | c.72-24G>T | Intron (SNP) | VAF 64/174 reads (37%) | catalogued as COSV52375187; called by muse, mutect2, varscan2
